Somatic mutation profile of tumor specimen TCGA-55-8619-01A (aliquot TCGA-55-8619-01A-11D-2393-08) from TCGA case TCGA-55-8619, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 72.9 years (26,616 days).
Specimen TCGA-55-8619-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 70b66624-d30b-4fed-b7aa-248efd0ac7c3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-8619-10A (Blood Derived Normal), aliquot TCGA-55-8619-10A-01D-2393-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6a1c704a-961a-4fe9-842c-620227b5c785

The open-access MAF lists 21 somatic variants for this specimen: 15 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 12, Silent 6, Nonsense Mutation 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1D | c.6100C>T p.R2034W (on ENST00000350061 / NM_001128840.3; = p.R2054W on NM_000720.4) | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.772); catalogued as rs142692903; called by muse, mutect2
- CPAMD8 | c.2764G>A p.V922I (on ENST00000651564; = p.V875I on NM_015692.5) | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.789); catalogued as rs199613595, COSV71595963; called by muse, mutect2
- FAM47A | c.2069G>A p.R690H | Missense Mutation (SNP) | VAF 19/199 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0.361); catalogued as COSV60495353, COSV60496508; called by muse, mutect2
- GATA4 | c.647A>T p.E216V | Missense Mutation (SNP) | VAF 26/328 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100632846; called by muse, mutect2
- HECW1 | c.3889C>T p.R1297W | Missense Mutation (SNP) | VAF 18/250 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1252894599, COSV67825553; called by muse, mutect2
- MRPS12 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99671259; called by muse, mutect2
- PDE4B | c.1507C>T p.R503C | Missense Mutation (SNP) | VAF 18/242 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs758382247, COSV58496677; called by muse, mutect2
- PKHD1 | c.2280-1G>T p.X760_splice | Splice Site (SNP) | VAF 7/89 reads (8%) | catalogued as CS149128, COSV100582696; called by muse, mutect2
- PSEN1 | c.392A>G p.H131R | Missense Mutation (SNP) | VAF 14/213 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.258); catalogued as rs1555353072, CM134482, COSV99997778; called by muse, mutect2
- RREB1 | c.499C>T p.R167* | Nonsense Mutation (SNP) | VAF 18/286 reads (6%) | catalogued as rs1298135588, COSV100619298; called by muse, mutect2
- THEMIS | c.1052C>T p.T351M | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200529297, COSV64069470; called by muse, mutect2
- TRO | c.3898G>A p.G1300S | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.26); catalogued as rs779087655, COSV99436274; called by muse, mutect2
- ZNF256 | c.1828A>G p.K610E | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as COSV56597246, COSV99990780; called by muse, mutect2
- ZNF473 | c.1567C>T p.R523C | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as rs765882894, COSV54521828; called by muse, mutect2, varscan2
- NRK | c.1367_1369delinsT p.K456Ifs*3 | Frame Shift Del (DEL) | VAF 10/70 reads (14%) | called by pindel, varscan2*
- CCDC198 | c.355C>T p.L119= | Silent (SNP) | VAF 12/116 reads (10%) | catalogued as COSV99371221; called by muse, mutect2, varscan2
- EVC | c.1437G>A p.P479= | Silent (SNP) | VAF 7/89 reads (8%) | catalogued as rs112861104; called by muse, mutect2
- PDZD7 | c.408G>C p.V136= | Silent (SNP) | VAF 9/92 reads (10%) | catalogued as COSV100931613; called by muse, mutect2
- PTGIR | c.879C>A p.I293= | Silent (SNP) | VAF 12/136 reads (9%) | catalogued as COSV99354962; called by muse, mutect2
- TBX5 | c.612C>T p.H204= | Silent (SNP) | VAF 26/332 reads (8%) | catalogued as rs200326827, COSV100091084; called by muse, mutect2
- UMODL1 | c.1380G>A p.A460= | Silent (SNP) | VAF 24/225 reads (11%) | catalogued as rs139481180; called by muse, mutect2, varscan2
